Somatic mutation profile of tumor specimen TCGA-D7-8574-01A (aliquot TCGA-D7-8574-01A-13D-2340-08) from TCGA case TCGA-D7-8574, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 72.8 years (26,586 days).
Specimen TCGA-D7-8574-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c5f595a-b0a7-4397-8c23-8d5e4fa64529.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-8574-10A (Blood Derived Normal), aliquot TCGA-D7-8574-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68d8756c-9a13-49ad-aae5-795ce1b9dfe1

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Nonsense Mutation 3, Splice Region 2, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.5367C>G p.F1789L | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99899960; called by muse, mutect2
- ARMC6 | c.1490G>A p.G497D (on ENST00000392336; = p.G472D on NM_033415.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV99522994; called by muse, mutect2
- C20orf194 | c.409-1G>A p.X137_splice | Splice Site (SNP) | VAF 14/168 reads (8%) | catalogued as COSV52700520; called by muse, mutect2
- CACNA1G | c.4151G>A p.R1384Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260560600, COSV61734134; ClinVar: uncertain significance; called by muse, mutect2
- CD2AP | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as COSV63759458; called by muse, mutect2
- CDH1 | c.532-1G>T p.X178_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as COSV55729230, COSV55734907, COSV55735088; called by muse, mutect2, varscan2
- CNOT1 | c.698A>C p.D233A | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV57777000; called by muse, mutect2
- DOK6 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101234832; called by muse, mutect2
- FSCN3 | c.840C>T p.Y280= | Splice Region (SNP) | VAF 3/49 reads (6%) | catalogued as rs1236938690; called by muse, mutect2
- GRM1 | c.2430C>A p.Y810* | Nonsense Mutation (SNP) | VAF 6/106 reads (6%) | catalogued as COSV99268066; called by muse, mutect2
- HSF2 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs933377374, COSV63774334; called by muse, mutect2
- IL1B | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 6/110 reads (5%) | catalogued as COSV99641970; called by muse, mutect2
- ITGA8 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as rs375972086, COSV65226619; called by mutect2, varscan2
- MACROD2 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1256648187, COSV53975817, COSV54059394; called by muse, mutect2
- MAGEB10 | c.795C>A p.N265K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63312300; called by muse, mutect2, varscan2
- ME2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.479); catalogued as COSV58424497; called by muse, mutect2
- MME | c.1914C>T p.H638= | Splice Region (SNP) | VAF 9/98 reads (9%) | catalogued as rs199578318, COSV64709286; called by muse, mutect2, varscan2
- OLFML2B | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs779675906, COSV54199023; called by muse, mutect2
- OR14J1 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs769244586, COSV65845719; called by muse, mutect2
- PCDH19 | c.3131G>T p.C1044F (on ENST00000373034 / NM_001184880.2; = p.C996F on NM_020766.3) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); catalogued as COSV55268343, COSV55268629; called by muse, mutect2
- RANBP2 | c.9124C>A p.Q3042K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.055); catalogued as COSV51705835; called by muse, mutect2
- RDH8 | c.418C>A p.R140S (on ENST00000651512; = p.R120S on NM_015725.4) | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV50676863, COSV50678150; called by muse, mutect2
- SPPL2C | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs200992535, COSV61293364; called by muse, mutect2
- CD93 | c.1731C>T p.D577= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs750953262, COSV55663341; called by muse, mutect2
- CNN3 | c.276T>C p.A92= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV64637416; called by muse, mutect2, varscan2
- CREB3L3 | c.129C>T p.G43= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as rs1180896891, COSV50243882; called by muse, mutect2
- NHS | c.3537G>A p.L1179= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV66279784; called by muse, mutect2, varscan2
- PPFIBP1 | c.2475G>A p.A825= (on ENST00000318304 / NM_177444.3; = p.A819= on NM_003622.4) | Silent (SNP) | VAF 20/338 reads (6%) | catalogued as rs746681298, COSV57290047, COSV99945708; called by muse, mutect2
- RABEPK | c.549A>G p.P183= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV52337430; called by muse, mutect2
- SLC1A7 | c.934C>T p.L312= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV65200802; called by muse, mutect2
- SMIM29 | c.180C>T p.P60= (on ENST00000394990 / NM_001008704.3; = p.P80= on NM_178508.5) | Silent (SNP) | VAF 15/151 reads (10%) | catalogued as COSV58988773; called by muse, mutect2, varscan2
- SNORD93 | n.21A>T | RNA (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
